Somatic mutation profile of tumor specimen C3L-02125-07 (aliquot CPT0197250006) from CPTAC case C3L-02125, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G3; Age at diagnosis: 68.0 years (24,837 days).
Specimen C3L-02125-07: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36156541-e00d-4e36-a24d-30e227609e97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02125-32 (Blood Derived Normal), aliquot CPT0199940002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffa3344f-12e5-4497-b1a9-b3cc343749e6

The open-access MAF lists 95 somatic variants for this specimen: 68 protein-altering or splice-affecting, 18 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 18, Nonsense Mutation 8, Intron 6, In Frame Del 2, 3'UTR 2, Splice Site 1, Frame Shift Del 1, Frame Shift Ins 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABRA1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 152/292 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs727503940, COSV50119921, COSV99195708; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 556/693 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BIRC6 | c.5345G>A p.R1782Q | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1158247243, COSV70197748; called by muse, mutect2
- CCER1 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100726980; called by muse, mutect2, varscan2
- CD3E | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs760138592; called by muse, mutect2
- CGB3 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 85/392 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.215); catalogued as rs1191498734; called by muse, varscan2
- CLCF1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 121/233 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); catalogued as rs761887384, COSV56861697, COSV56862732; called by muse, mutect2, varscan2
- EEF1A2 | c.616C>G p.P206A | Missense Mutation (SNP) | VAF 80/159 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53205487; called by muse, mutect2
- EIF2B3 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 145/362 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.045); catalogued as rs1442706104; called by muse, mutect2, varscan2
- ENTPD5 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as rs761661105, COSV58221517; called by muse, mutect2, varscan2
- FRMD7 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 50/74 reads (68%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs943531530; called by muse, mutect2, varscan2
- GPR31 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 168/361 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.338); catalogued as rs756916147, COSV64761079; called by muse, mutect2, varscan2
- HDX | c.268C>G p.R90G | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV52975467; called by muse, mutect2
- KAZN | c.1907G>A p.S636N | Missense Mutation (SNP) | VAF 115/147 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV65724547; called by muse, mutect2, varscan2
- KMT2C | c.10279C>T p.Q3427* | Nonsense Mutation (SNP) | VAF 105/226 reads (46%) | catalogued as COSV51484133; called by muse, mutect2, varscan2
- LTB4R2 | c.1048C>T p.R350C (on ENST00000528054; = p.R319C on NM_019839.5) | Missense Mutation (SNP) | VAF 170/282 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as rs1328785575; called by muse, mutect2, varscan2
- MAP3K14 | c.2293G>T p.V765F | Missense Mutation (SNP) | VAF 76/421 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60922917; called by muse, mutect2, varscan2
- MFGE8 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 222/303 reads (73%) | SIFT tolerated (0.59); PolyPhen benign (0.296); catalogued as COSV51555783; called by muse, mutect2, varscan2
- MYBL2 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 89/238 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV53828365; called by muse, mutect2, varscan2
- NRG3 | c.1769A>C p.Y590S (on ENST00000404547 / NM_001370084.1; = p.Y566S on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/476 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.943); catalogued as COSV64551158; called by muse, mutect2
- PCNX2 | c.4084C>T p.R1362* | Nonsense Mutation (SNP) | VAF 39/155 reads (25%) | catalogued as rs1392209488, COSV99268785; called by muse, mutect2, varscan2
- PIK3CA | c.371C>A p.P124Q | Missense Mutation (SNP) | VAF 139/209 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as COSV55927445, COSV55977327; called by muse, mutect2, varscan2
- POLR2I | c.21C>G p.Y7* | Nonsense Mutation (SNP) | VAF 102/368 reads (28%) | catalogued as rs772329724, COSV52900093; called by muse, mutect2, varscan2
- POLR3B | c.2570C>T p.T857I | Missense Mutation (SNP) | VAF 80/343 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs777896021; called by muse, mutect2, varscan2
- PRRT3 | c.2744G>A p.S915N | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1052458614; called by muse, mutect2
- RHPN1 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1032429512; called by muse, mutect2
- SLC6A5 | c.2070+1G>A p.X690_splice | Splice Site (SNP) | VAF 112/361 reads (31%) | catalogued as rs770660705, CD127487, COSV54229382, COSV54232229; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTB | c.997_999del p.P333del | In Frame Del (DEL) | VAF 265/401 reads (66%) | called by pindel, varscan2
- ASXL2 | c.3268T>G p.F1090V | Missense Mutation (SNP) | VAF 216/390 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- BCO1 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 196/264 reads (74%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- CD6 | c.1652C>A p.S551Y | Missense Mutation (SNP) | VAF 38/474 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.642); called by muse, mutect2
- CNNM1 | c.1962G>T p.K654N | Missense Mutation (SNP) | VAF 178/223 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- CREB3L3 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 32/378 reads (8%) | called by muse, mutect2
- CTNNBL1 | c.1139G>C p.R380P | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- CYRIA | c.484A>G p.I162V | Missense Mutation (SNP) | VAF 150/356 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DICER1 | c.1712G>A p.S571N | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2
- EIF3A | c.203A>G p.K68R | Missense Mutation (SNP) | VAF 7/202 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ENOSF1 | c.680-5C>T | Splice Region (SNP) | VAF 137/312 reads (44%) | called by muse, mutect2, varscan2
- GAREM2 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 46/658 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.17); called by muse, mutect2
- GYS1 | c.1117A>T p.N373Y | Missense Mutation (SNP) | VAF 40/372 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCN4 | c.340G>T p.G114W | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- HTRA3 | c.71C>G p.P24R | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- KMT5B | c.1458A>T p.K486N | Missense Mutation (SNP) | VAF 78/291 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGED1 | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 16/253 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.091); called by muse, mutect2
- MUC5B | c.9820G>A p.V3274I | Missense Mutation (SNP) | VAF 95/752 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO7A | c.3494C>G p.P1165R | Missense Mutation (SNP) | VAF 221/392 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NALCN | c.2548del p.C850Afs*21 | Frame Shift Del (DEL) | VAF 114/346 reads (33%) | called by mutect2, pindel, varscan2
- OR8J3 | c.890T>G p.V297G | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PASK | c.3722C>G p.T1241S | Missense Mutation (SNP) | VAF 135/432 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- PCLO | c.12918A>C p.K4306N | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- PELI3 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 97/169 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- PIK3CA | c.1801C>A p.L601I | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PRKAG1 | c.764_805del p.Y255_R269delins* | Nonsense Mutation (DEL) | VAF 22/236 reads (9%) | called by mutect2, pindel
- RAPGEF6 | c.4198A>T p.I1400F | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- RFWD3 | c.1472A>T p.Q491L | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RIN3 | c.2496_2497dup p.A833Gfs*14 | Frame Shift Ins (INS) | VAF 68/159 reads (43%) | called by mutect2, pindel, varscan2
- RNASE2 | c.274A>T p.N92Y | Missense Mutation (SNP) | VAF 221/636 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RNF217 | c.657C>A p.D219E | Missense Mutation (SNP) | VAF 17/332 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.058); called by muse, mutect2
- RPS6KA2 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 98/254 reads (39%) | called by muse, mutect2, varscan2
- SLCO2A1 | c.1079C>G p.S360* | Nonsense Mutation (SNP) | VAF 71/146 reads (49%) | called by muse, mutect2, varscan2
- SYBU | c.734G>A p.R245K (on ENST00000276646 / NM_001099754.2; = p.R244K on NM_017786.6) | Missense Mutation (SNP) | VAF 87/282 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- TNIP3 | c.859G>C p.A287P | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.027); called by muse, mutect2
- TUB | c.125_127del p.R42del (on ENST00000299506 / NM_177972.3; = p.R97del on NM_003320.4) | In Frame Del (DEL) | VAF 72/291 reads (25%) | called by mutect2, pindel, varscan2
- TYK2 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 50/284 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- VIPR2 | c.1151G>T p.C384F | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- WDR75 | c.950T>C p.I317T | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- ZC3H13 | c.2180G>C p.R727T | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.382); called by muse, mutect2
- ZNF8 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 23/334 reads (7%) | called by muse, mutect2
- ATP13A5 | c.279C>G p.L93= | Silent (SNP) | VAF 59/202 reads (29%) | called by muse, mutect2, varscan2
- CHAF1A | c.2286C>G p.R762= | Silent (SNP) | VAF 7/130 reads (5%) | called by muse, mutect2
- CLEC14A | c.156G>A p.E52= | Silent (SNP) | VAF 108/360 reads (30%) | catalogued as rs1248852773; called by muse, mutect2, varscan2
- DDX17 | c.417G>A p.P139= | Silent (SNP) | VAF 16/284 reads (6%) | catalogued as rs141425209; called by muse, mutect2
- EOLA1 | c.303C>G p.P101= | Silent (SNP) | VAF 104/158 reads (66%) | catalogued as rs782752836, COSV63734049, COSV63734079, COSV63734090; called by muse, mutect2, varscan2
- G6PC | c.93C>T p.I31= | Silent (SNP) | VAF 424/516 reads (82%) | catalogued as COSV53831521; called by muse, mutect2, varscan2
- GAK | c.2182A>C p.R728= | Silent (SNP) | VAF 15/292 reads (5%) | called by muse, mutect2
- LCE6A | c.183G>A p.L61= | Silent (SNP) | VAF 55/144 reads (38%) | called by muse, mutect2, varscan2
- LMO1 | c.291C>A p.A97= | Silent (SNP) | VAF 61/235 reads (26%) | catalogued as rs1467856890; called by muse, mutect2, varscan2
- NLGN3 | c.1182C>T p.G394= (on ENST00000358741 / NM_181303.2; = p.G374= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 102/143 reads (71%) | catalogued as COSV62443702, COSV62444244; called by muse, mutect2, varscan2
- NTRK2 | c.1659C>T p.F553= (on ENST00000323115 / NM_001369534.1; = p.F569= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 208/313 reads (66%) | called by muse, mutect2, varscan2
- OR2AP1 | c.651A>T p.A217= | Silent (SNP) | VAF 89/357 reads (25%) | catalogued as rs1256573066; called by muse, mutect2, varscan2
- PAPPA2 | c.480C>T p.A160= | Silent (SNP) | VAF 132/329 reads (40%) | catalogued as rs1359415236; called by muse, mutect2, varscan2
- PCDHB4 | c.1338C>T p.N446= | Silent (SNP) | VAF 145/614 reads (24%) | catalogued as rs1273401894, COSV52021411; called by muse, mutect2, varscan2
- PCGF1 | c.267C>A p.I89= | Silent (SNP) | VAF 181/509 reads (36%) | called by muse, mutect2, varscan2
- RBMXL2 | c.759C>A p.P253= | Silent (SNP) | VAF 12/173 reads (7%) | called by muse, mutect2
- SP7 | c.573G>A p.L191= | Silent (SNP) | VAF 44/196 reads (22%) | called by muse, mutect2, varscan2
- ZNF281 | c.231G>C p.V77= | Silent (SNP) | VAF 11/140 reads (8%) | called by muse, mutect2
- AGR3 | c.*34G>C | 3'UTR (SNP) | VAF 31/56 reads (55%) | called by muse, mutect2, varscan2
- DLG4 | c.30+3287G>A | Intron (SNP) | VAF 177/241 reads (73%) | catalogued as rs1207725809; called by muse, mutect2, varscan2
- GABRG2 | c.1248+26A>T | Intron (SNP) | VAF 58/259 reads (22%) | called by muse, mutect2, varscan2
- PNKD | c.237-16571G>C | Intron (SNP) | VAF 38/103 reads (37%) | catalogued as rs1358374663; called by muse, mutect2, varscan2
- REEP5 | c.119-29C>T | Intron (SNP) | VAF 85/110 reads (77%) | catalogued as rs555361006; called by muse, mutect2, varscan2
- RUNX1T1 | c.1280-3843G>A | Intron (SNP) | VAF 50/123 reads (41%) | called by muse, mutect2, varscan2
- SEPTIN2 | c.-119+866G>T | Intron (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- TMED1 | c.*638G>T | 3'UTR (SNP) | VAF 17/420 reads (4%) | called by muse, mutect2
- TTC3P1 | n.5375G>A | RNA (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
